Somatic mutation profile of tumor specimen TCGA-A6-3808-01A (aliquot TCGA-A6-3808-01A-01W-0995-10) from TCGA case TCGA-A6-3808, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 73.0 years (26,666 days).
Specimen TCGA-A6-3808-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 256a0967-dc25-4b9f-8514-45c46eab451a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-3808-10A (Blood Derived Normal), aliquot TCGA-A6-3808-10A-01D-1459-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d724bb1f-4231-4577-b203-de227a0ed0d6

The open-access MAF lists 150 somatic variants for this specimen: 115 protein-altering or splice-affecting, 29 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 99, Silent 29, Nonsense Mutation 8, Frame Shift Ins 5, RNA 3, Frame Shift Del 2, 3'UTR 2, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANTXR2 | c.1073dup p.A359Cfs*13 | Frame Shift Ins (INS) | VAF 20/137 reads (15%) | catalogued as rs312262690; ClinVar: pathogenic; called by pindel, varscan2
- APC | c.2413C>T p.R805* | Nonsense Mutation (SNP) | VAF 40/208 reads (19%) | catalogued as rs587779783, CM960067, COSV57322578; ClinVar: pathogenic; called by muse, mutect2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 10/45 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 28/152 reads (18%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- SAMHD1 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 114/480 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs515726145, CM093963, COSV99483854; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC011462.1 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as rs768944277, COSV54199618; called by muse, mutect2, varscan2
- AC136428.1 | c.323A>G p.E108G | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.302); catalogued as COSV101434948; called by muse, mutect2, varscan2
- ACP7 | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV58700773; called by muse, mutect2
- ACSS2 | c.1994G>T p.R665L | Missense Mutation (SNP) | VAF 144/536 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99404269; called by muse, mutect2, varscan2
- ACVR1B | c.656G>A p.G219E | Missense Mutation (SNP) | VAF 231/478 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57774861; called by muse, mutect2, varscan2
- ADAM28 | c.150+2T>A p.X50_splice | Splice Site (SNP) | VAF 59/249 reads (24%) | catalogued as rs1182475846, COSV99738045; called by muse, mutect2, varscan2
- AFF2 | c.277C>T p.H93Y | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs200850740, COSV100649268; called by muse, mutect2, varscan2
- AGPAT4 | c.614T>C p.L205S | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV100211080; called by muse, mutect2, varscan2
- AMER1 | c.1849G>T p.E617* | Nonsense Mutation (SNP) | VAF 54/126 reads (43%) | catalogued as COSV57661863; called by muse, mutect2, varscan2
- ARL13A | c.635A>G p.E212G | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV65880371; called by muse, mutect2, varscan2
- ARMC4 | c.26C>T p.T9M | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs181484327, COSV100536459; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASNS | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); catalogued as COSV51556376; called by muse, mutect2, varscan2
- B3GNT9 | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.07); catalogued as COSV54629571; called by muse, mutect2
- BNC1 | c.1135G>A p.V379I | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1415662180, COSV61756473; called by muse, varscan2
- C11orf16 | c.518G>A p.G173D | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58169182; called by muse, mutect2, varscan2
- CACNG3 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV50065182, COSV99135432; called by muse, mutect2, varscan2
- CAND1 | c.1986C>A p.N662K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as COSV73389711; called by muse, mutect2
- CCDC142 | c.513C>G p.I171M | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.443); catalogued as COSV99281983; called by muse, varscan2
- CCR3 | c.905C>A p.A302D | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100656373; called by muse, mutect2, varscan2
- CDH2 | c.2423G>A p.R808Q | Missense Mutation (SNP) | VAF 67/247 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1313840328, COSV52270856; called by muse, mutect2, varscan2
- CHCHD2 | c.448T>G p.L150V | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.178); catalogued as COSV68170181; called by muse, mutect2, varscan2
- CHMP7 | c.66dup p.E23Rfs*115 | Frame Shift Ins (INS) | VAF 6/55 reads (11%) | catalogued as rs768597444; called by pindel, varscan2
- COL6A6 | c.1549G>T p.A517S | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.925); catalogued as COSV100649970; called by muse, mutect2, varscan2
- COL6A6 | c.1550C>T p.A517V | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.932); catalogued as COSV100649971; called by muse, mutect2, varscan2
- COLEC12 | c.1740dup p.G581Rfs*17 | Frame Shift Ins (INS) | VAF 10/46 reads (22%) | catalogued as rs750635929; called by mutect2, varscan2
- CRISP3 | c.373C>A p.L125I (on ENST00000371159 / NM_001368123.1; = p.L107I on NM_006061.4) | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV99538674; called by muse, mutect2
- CRYL1 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV100004213; called by muse, mutect2, varscan2
- CSMD1 | c.9886G>A p.G3296S (on ENST00000520002; = p.G3295S on NM_033225.6) | Missense Mutation (SNP) | VAF 54/430 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757638862, COSV100145033; called by muse, mutect2, varscan2
- CTNND2 | c.1351G>A p.G451S | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs150121479, COSV58875865; called by muse, mutect2, varscan2
- CYP7A1 | c.206G>A p.C69Y | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56963781; called by muse, mutect2
- DST | c.16875G>A p.W5625* (on ENST00000361203 / NM_001374722.1; = p.W3322* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 76/318 reads (24%) | catalogued as COSV55018738, COSV99752464; called by muse, mutect2, varscan2
- DUOX2 | c.4191A>C p.K1397N | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as COSV101199615; called by muse, mutect2, varscan2
- E2F8 | c.1141A>C p.N381H | Missense Mutation (SNP) | VAF 16/596 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100001363; called by muse, mutect2
- ECM2 | c.1897C>A p.L633I | Missense Mutation (SNP) | VAF 109/736 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60743092; called by muse, mutect2, varscan2
- EDNRA | c.703C>G p.Q235E | Missense Mutation (SNP) | VAF 92/372 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60100565; called by muse, mutect2, varscan2
- EID3 | c.752C>A p.S251Y | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100723350; called by muse, mutect2, varscan2
- ERCC6L2 | c.1240C>T p.Q414* | Nonsense Mutation (SNP) | VAF 96/395 reads (24%) | catalogued as COSV56631566, COSV56633407; called by muse, mutect2, varscan2
- EXOC6B | c.2392G>A p.V798M | Missense Mutation (SNP) | VAF 98/460 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as rs778555637, COSV99723169; called by muse, mutect2, varscan2
- FERD3L | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV51762036; called by muse, mutect2, varscan2
- FLG | c.6232G>A p.G2078S | Missense Mutation (SNP) | VAF 40/258 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV64250544; called by muse, mutect2, varscan2
- FN1 | c.3851G>A p.R1284H | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); catalogued as rs1390228361, COSV60558750; called by muse, mutect2, varscan2
- FNIP2 | c.1982G>A p.G661D | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV52443107, COSV52446522; called by muse, mutect2, varscan2
- FRY | c.284C>T p.T95I | Missense Mutation (SNP) | VAF 80/209 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs760404697, COSV100968895; called by muse, varscan2
- FXR1 | c.1091T>C p.L364P | Missense Mutation (SNP) | VAF 50/251 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99976227; called by muse, mutect2, varscan2
- GGT7 | c.1093G>A p.V365M | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs766936948, COSV60540487; called by muse, mutect2, varscan2
- GRID1 | c.1641G>T p.K547N | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV100022507; called by muse, mutect2, varscan2
- GRIK2 | c.950C>T p.T317M | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.61); catalogued as rs118175062; called by muse, varscan2
- GSK3B | c.916C>T p.R306* (on ENST00000264235 / NM_001146156.2; = p.R319* on NM_002093.4) | Nonsense Mutation (SNP) | VAF 62/215 reads (29%) | catalogued as rs768552900, COSV51774118; called by muse, mutect2, varscan2
- GTF2IRD1 | c.1247G>A p.R416H | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56086476; called by muse, mutect2, varscan2
- HDAC9 | c.2531G>A p.R844H | Missense Mutation (SNP) | VAF 67/314 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV67766183; called by muse, mutect2, varscan2
- IGHG2 | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.547); catalogued as rs368453065; called by muse, mutect2, varscan2
- INHBA | c.643A>G p.K215E | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.593); catalogued as COSV99637296; called by muse, mutect2, varscan2
- IPO7 | c.2411T>G p.L804R | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV101121793; called by muse, mutect2
- JAKMIP2 | c.1186G>T p.V396F | Missense Mutation (SNP) | VAF 174/749 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV99507630; called by muse, mutect2, varscan2
- KMT2D | c.692T>G p.V231G | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99978536; called by muse, mutect2, varscan2
- KRT1 | c.777G>A p.M259I | Missense Mutation (SNP) | VAF 66/312 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.739); catalogued as rs756537688, COSV99358550; called by muse, mutect2, varscan2
- LHCGR | c.1612G>T p.A538S | Missense Mutation (SNP) | VAF 279/1047 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54302116, COSV99683320; called by muse, mutect2, varscan2
- LIMCH1 | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1561943442, COSV100573524; called by muse, mutect2, varscan2
- LSM11 | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 73/426 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs141199540; called by muse, mutect2, varscan2
- MCHR1 | c.573G>A p.M191I | Missense Mutation (SNP) | VAF 75/281 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.174); catalogued as rs748371706, COSV50761119; called by muse, mutect2, varscan2
- MPDZ | c.3508C>T p.R1170* | Nonsense Mutation (SNP) | VAF 106/438 reads (24%) | catalogued as rs200131423; called by muse, varscan2
- MPDZ | c.869C>A p.A290D | Missense Mutation (SNP) | VAF 92/432 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100061259; called by muse, mutect2, varscan2
- MTG1 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.384); catalogued as rs540025351, COSV100448741; called by muse, varscan2
- MUC16 | c.25108C>A p.L8370I | Missense Mutation (SNP) | VAF 109/543 reads (20%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.246); catalogued as COSV101198691, COSV67451550; called by muse, mutect2, varscan2
- MYH6 | c.4084G>A p.V1362I | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs768398107, COSV100676360; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO1E | c.1396G>T p.V466L | Missense Mutation (SNP) | VAF 48/194 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.817); catalogued as rs773105280, COSV99894777; called by muse, mutect2, varscan2
- NUP214 | c.5447G>A p.G1816D | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV100845176; called by muse, mutect2, varscan2
- OR2A14 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.465); catalogued as rs776312245, COSV101376504, COSV68718729; called by muse, mutect2, varscan2
- OR3A1 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.271); catalogued as rs768101149, COSV60163907; called by muse, varscan2
- OR4A15 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.005); catalogued as rs545781371, COSV100124329, COSV59034345; called by muse, varscan2
- PCDH15 | c.3679G>A p.D1227N | Missense Mutation (SNP) | VAF 171/801 reads (21%) | SIFT tolerated (0.96); PolyPhen benign (0.02); catalogued as rs368127988, COSV100217129; ClinVar: uncertain significance; called by muse, varscan2
- PCLO | c.1435C>T p.P479S | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.059); catalogued as COSV100428708; called by muse, mutect2, varscan2
- PGF | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as rs764795497, COSV53126039; called by muse, mutect2, varscan2
- PKIB | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752581156, COSV99236149; called by muse, mutect2, varscan2
- PLXND1 | c.5617G>A p.A1873T | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100139209; called by muse, mutect2, varscan2
- PRDM15 | c.754A>G p.N252D | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.023); catalogued as COSV99519522; called by muse, mutect2
- PRPF8 | c.5539G>A p.A1847T | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV59263729; called by muse, mutect2, varscan2
- RASSF5 | c.523G>C p.G175R | Missense Mutation (SNP) | VAF 49/197 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV62427557; called by muse, mutect2, varscan2
- RIMKLB | c.184A>G p.I62V | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100223797; called by muse, mutect2, varscan2
- SDK2 | c.2563G>A p.V855M | Missense Mutation (SNP) | VAF 52/253 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.041); catalogued as rs752790641, COSV101167090; called by muse, mutect2, varscan2
- SLC12A5 | c.529G>T p.A177S (on ENST00000454036 / NM_001134771.2; = p.A154S on NM_020708.5) | Missense Mutation (SNP) | VAF 15/436 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99715535, COSV99716028; called by muse, mutect2
- SLC15A2 | c.1549G>A p.V517M | Missense Mutation (SNP) | VAF 67/1155 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as rs372532662; called by muse, mutect2
- SLC7A11 | c.854A>T p.N285I | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99762973; called by muse, mutect2, varscan2
- SNAPC4 | c.1151C>T p.S384F | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100046912; called by muse, mutect2, varscan2
- SPATA31E1 | c.4207G>A p.A1403T | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.111); catalogued as rs778430286, COSV100350057; called by muse, mutect2, varscan2
- SPTA1 | c.3152G>A p.G1051E | Missense Mutation (SNP) | VAF 96/667 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as COSV100934538; called by muse, mutect2, varscan2
- SPTLC3 | c.529T>C p.Y177H | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV65464732; called by muse, mutect2, varscan2
- STAG3 | c.286C>A p.P96T | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs776921708, COSV57935477; called by muse, mutect2, varscan2
- SYNE1 | c.8480T>G p.V2827G (on ENST00000367255 / NM_182961.4; = p.V2834G on NM_033071.3) | Missense Mutation (SNP) | VAF 74/281 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV99556271; called by muse, mutect2, varscan2
- SYT16 | c.1808G>A p.R603H | Missense Mutation (SNP) | VAF 146/610 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs747375303, COSV70856031; called by muse, mutect2, varscan2
- TBXT | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as COSV51620052; called by muse, mutect2, varscan2
- TGFBR2 | c.1322C>T p.S441F | Missense Mutation (SNP) | VAF 94/479 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM063206, COSV55446401; called by muse, mutect2, varscan2
- TMEM74 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 63/283 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs372486464; called by muse, mutect2, varscan2
- TMEM79 | c.890A>G p.N297S | Missense Mutation (SNP) | VAF 51/232 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs748534614, COSV99827791; called by muse, mutect2, varscan2
- TNKS | c.2075C>T p.A692V | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV100126405; called by muse, mutect2, varscan2
- TNR | c.386G>C p.S129T | Missense Mutation (SNP) | VAF 26/530 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99688206; called by muse, mutect2
- TNRC18 | c.8753C>T p.S2918L | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99786680; called by muse, mutect2, varscan2
- TPRX1 | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs764679465, COSV100445552; called by muse, mutect2, varscan2
- TRIP12 | c.4145A>G p.N1382S | Missense Mutation (SNP) | VAF 79/379 reads (21%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.931); catalogued as rs774847694, COSV52273428; called by muse, mutect2, varscan2
- USP17L2 | c.1406C>A p.S469* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as rs201297814, COSV61556850; called by muse, mutect2, varscan2
- ZFR2 | c.2669G>A p.R890Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779501283; called by muse, mutect2
- ZNF292 | c.4675T>A p.S1559T | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.062); catalogued as COSV100370001; called by muse, mutect2
- ZNF34 | c.943A>G p.T315A | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58641454; called by muse, mutect2, varscan2
- ZNF385D | c.1129C>T p.R377W | Missense Mutation (SNP) | VAF 52/215 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55749022; called by muse, mutect2, varscan2
- ZNF750 | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.095); catalogued as rs752878414, COSV53962717; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2608G>A p.G870R | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ECHS1 | c.147_150del p.L49Ffs*3 | Frame Shift Del (DEL) | VAF 3/33 reads (9%) | called by mutect2, pindel
- NGRN | c.505_514del p.V169Lfs*20 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- TGIF1 | c.4dup p.D2? (on ENST00000330513 / NM_001374396.1; = p.D22Gfs*35 on NM_003244.4) | Frame Shift Ins (INS) | VAF 16/84 reads (19%) | called by mutect2, pindel, varscan2
- UTRN | c.1148dup p.D384Rfs*6 | Frame Shift Ins (INS) | VAF 10/68 reads (15%) | called by mutect2, pindel, varscan2
- ABCA4 | c.3585A>T p.L1195= | Silent (SNP) | VAF 71/336 reads (21%) | catalogued as COSV64678655; called by muse, mutect2, varscan2
- AGMAT | c.1056C>G p.V352= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV65436363; called by muse, mutect2, varscan2
- AHNAK2 | c.14166C>T p.V4722= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV100316239; called by mutect2, varscan2
- ATP13A1 | c.2052C>T p.R684= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs1347277541, COSV52291655; called by muse, mutect2, varscan2
- CACNA1E | c.3489T>C p.I1163= | Silent (SNP) | VAF 18/98 reads (18%) | catalogued as rs775761051, COSV100701463; called by muse, mutect2, varscan2
- CCDC186 | c.1768C>T p.L590= | Silent (SNP) | VAF 92/314 reads (29%) | catalogued as COSV65162206; called by muse, mutect2, varscan2
- CHSY1 | c.1410C>T p.H470= | Silent (SNP) | VAF 22/127 reads (17%) | catalogued as rs750435215, COSV54255360, COSV54256246; called by muse, mutect2, varscan2
- CSMD1 | c.639C>T p.R213= | Silent (SNP) | VAF 56/268 reads (21%) | catalogued as rs777613399, COSV68233215; called by muse, varscan2
- CUL9 | c.6975G>A p.P2325= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as rs150159860; called by muse, mutect2, varscan2
- FAM228A | c.459C>T p.A153= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs774404104, COSV54596511; called by muse, mutect2, varscan2
- FANCM | c.642T>C p.D214= | Silent (SNP) | VAF 28/640 reads (4%) | catalogued as COSV99360803; called by muse, mutect2
- FILIP1L | c.2823G>A p.T941= (on ENST00000354552 / NM_182909.3; = p.T701= on NM_014890.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 564/2223 reads (25%) | catalogued as rs372889125; called by muse, mutect2, varscan2
- GNL2 | c.492C>T p.I164= | Silent (SNP) | VAF 77/310 reads (25%) | catalogued as rs944187672, COSV66080090; called by muse, mutect2, varscan2
- GRIK4 | c.1278C>T p.N426= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV70807605; called by muse, mutect2, varscan2
- HPS4 | c.1857G>A p.P619= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs373421312; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IMPDH2 | c.420C>T p.C140= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as rs530770243, COSV58709076; called by muse, mutect2, varscan2
- LPAR6 | c.589C>T p.L197= | Silent (SNP) | VAF 62/359 reads (17%) | catalogued as COSV99923618; called by muse, mutect2, varscan2
- NUTM2F | c.837G>A p.A279= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs753871072, COSV99479949; called by muse, mutect2, varscan2
- OCA2 | c.897G>A p.T299= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as rs149191701, COSV62360890; called by muse, mutect2, varscan2
- PCDHA13 | c.1767C>T p.H589= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV99165210; called by muse, mutect2, varscan2
- RRAGC | c.867C>T p.I289= | Silent (SNP) | VAF 44/193 reads (23%) | catalogued as rs764907659, COSV65932115; called by muse, mutect2, varscan2
- SDK2 | c.2349C>T p.T783= | Silent (SNP) | VAF 67/191 reads (35%) | catalogued as rs370359527; called by muse, mutect2, varscan2
- SIDT2 | c.1519C>T p.L507= | Silent (SNP) | VAF 3/45 reads (7%) | catalogued as COSV99637307; called by muse, mutect2
- SIRPB2 | c.777C>T p.T259= | Silent (SNP) | VAF 48/292 reads (16%) | catalogued as COSV100708421; called by muse, mutect2
- SSH1 | c.873C>T p.L291= | Silent (SNP) | VAF 33/584 reads (6%) | catalogued as COSV100425384; called by muse, mutect2
- THBS2 | c.1020G>T p.T340= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV100827724, COSV64682409; called by muse, mutect2, varscan2
- TRPC1 | c.1263A>G p.E421= (on ENST00000476941 / NM_001251845.2; = p.E387= on NM_003304.4) | Silent (SNP) | VAF 105/490 reads (21%) | catalogued as COSV56430711; called by muse, mutect2, varscan2
- UGGT2 | c.292C>T p.L98= | Silent (SNP) | VAF 26/745 reads (3%) | catalogued as COSV100942487, COSV100942582; called by muse, mutect2
- XYLT2 | c.925C>A p.R309= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as rs753449527, COSV50022605; called by muse, mutect2, varscan2
- C21orf62 | c.*3T>C | 3'UTR (SNP) | VAF 42/169 reads (25%) | catalogued as COSV101212294; called by muse, mutect2, varscan2
- C8orf86 | n.904G>A | RNA (SNP) | VAF 20/102 reads (20%) | catalogued as COSV63935796; called by muse, varscan2
- FSHB | c.*1A>T | 3'UTR (SNP) | VAF 8/38 reads (21%) | catalogued as COSV99569338; called by muse, mutect2
- MIR519E | n.68_71del | RNA (DEL) | VAF 70/332 reads (21%) | called by pindel, varscan2
- PCDHA9 | c.2394+58C>A | Intron (SNP) | VAF 5/16 reads (31%) | catalogued as rs868931837, COSV100969191; called by muse, mutect2, varscan2
- PKD1L2 | n.2777G>A | RNA (SNP) | VAF 9/47 reads (19%) | catalogued as rs1004125758; called by muse, mutect2, varscan2
